Gene-level copy-number profile of tumor specimen TCGA-46-6025-01A from TCGA case TCGA-46-6025, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 71.6 years (26,168 days).
Specimen TCGA-46-6025-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e113220a-9ace-4c0a-91d4-90502b6cf90d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-46-6025-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0cb8327-79ac-42ae-9243-41be647cf45e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 3,428; copy number 2: 24,092; copy number 3: 15,059; copy number 4: 11,582; copy number 5: 2,704; copy number 6: 1,657; copy number 7: 355; copy number 8: 618; copy number 9: 309.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-46-6025-01A-11D-1816-01): tumor purity 0.54, ploidy 2.83, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:20,534,457–21,232,404, 4 genes (within-gene range 0–2): CDKAL1, AL035090.1, AL513188.1, RNU6-150P.
- chr18:49,969,721–50,064,440, 2 genes: AC091044.1, ADAD1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,609 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,513,377–161,045,977, 145 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:238,777,049–239,915,452, 7 genes, copy number 6 (within-gene range 4–6): MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2.
- chr2:38,814–25,209,202, 387 genes, copy number 5 (broad region; genes not listed).
- chr2:182,909,115–196,593,684, 150 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:114,103,249–117,997,592, 40 genes, copy number 5: H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT, ZBTB20, AC093010.2, MIR568, ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2, MIR4796, ZBTB20-AS3, YBX1P3, ZBTB20-AS4, AC026341.1, EIF4E2P2, AC026341.2, AC026341.3, GAP43, AC092468.1, LSAMP, RN7SL815P, LSAMP-AS1, LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8, RNU6-1200P, AC092691.1, AC092691.2, LINC02024, AC092691.3.
- chr3:139,316,157–139,859,894, 17 genes, copy number 8: AC024933.2, AC024933.1, COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5.
- chr3:140,505,611–198,222,513, 1,006 genes, copy number 6–9 (broad region; genes not listed).
- chr5:17,490,967–45,895,970, 400 genes, copy number 5–7 (broad region; genes not listed).
- chr6:5,103,629–7,586,714, 48 genes, copy number 5–6 (within-gene range 3–6): LYRM4, MIR3691, FARS2, AL121978.1, AL021328.1, HNRNPA1P37, AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP.
- chr6:48,701,491–51,623,428, 40 genes, copy number 5: FO393412.1, AL391538.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL132799.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1.
- chr7:22,118,236–22,773,993, 10 genes, copy number 9 (within-gene range 2–9): RAPGEF5, RNA5SP227, STEAP1B, EEF1A1P6, AC002480.1, AC002480.2, IL6-AS1, IL6, MTCYBP42, AC073072.1.
- chr7:45,080,437–57,837,046, 268 genes, copy number 5–8 (broad region; genes not listed).
- chr9:35,609,979–38,147,561, 92 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr9:60,914,407–69,760,011, 194 genes, copy number 5 (broad region; genes not listed).
- chr9:130,713,016–130,887,675, 1 gene, copy number 5 (within-gene range 3–5): ABL1.
- chr9:130,892,707–138,203,325, 270 genes, copy number 5 (broad region; genes not listed).
- chr11:39,024,631–42,253,721, 20 genes, copy number 5: AC021723.2, AC021723.1, RNU6-99P, AC021749.1, AC021820.1, AC080100.1, LRRC4C, Y_RNA, AC090720.1, RNU6-365P, AC090138.1, LINC02741, AC021006.1, AC021006.2, LINC01499, AC023442.1, AC023442.3, AC023442.2, LINC02745, LINC02740.
- chr12:11,391,540–31,369,301, 346 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:31,396,390–31,396,501, 1 gene, copy number 5: RNU6-618P.
- chr12:46,358,188–46,876,784, 10 genes, copy number 5 (within-gene range 3–5): SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4.
- chr12:120,904,702–122,147,344, 46 genes, copy number 6 (within-gene range 3–6): AC069214.1, CLIC1P1, RPL12P33, HNF1A-AS1, HNF1A, C12orf43, OASL, OASL2P, AC079602.2, AC079602.3, SNORA70, AC079602.1, P2RX7, AC069209.2, AC069209.1, P2RX4, CAMKK2, ANAPC5, AC048337.1, RNF34, KDM2B, MIR7107, KDM2B-DT, RNU6-1004P, ORAI1, MORN3, AC084018.3, TMEM120B, RHOF, LINC01089, AC084018.1, AC084018.2, SETD1B, HPD, AC079360.1, AC069503.3, AC069503.5, PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P, CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP.
- chr15:31,923,438–37,491,103, 125 genes, copy number 6 (broad region; genes not listed).
- chr15:91,853,708–101,933,350, 214 genes, copy number 6–7 (within-gene range 4–7) (broad region; genes not listed).
- chr17:39,057,019–83,095,122, 1,579 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr22:26,390,667–29,319,679, 81 genes, copy number 6 (broad region; genes not listed).
- chr22:29,333,158–29,333,267, 2 genes, copy number 6: AC002059.2, SNORD125.
- chr22:46,481,329–50,801,309, 110 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
